Somatic mutation profile of tumor specimen TCGA-EB-A4IQ-01A (aliquot TCGA-EB-A4IQ-01A-12D-A25O-08) from TCGA case TCGA-EB-A4IQ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 42.5 years (15,516 days).
Specimen TCGA-EB-A4IQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83887fdf-fd38-48d9-a5cb-8fb29e7fe2ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A4IQ-10A (Blood Derived Normal), aliquot TCGA-EB-A4IQ-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edd361e4-c5f5-44c5-9342-fa43dbf02bcc

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 9 silent.
By variant classification: Silent 9, Missense Mutation 9.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSF3 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144907664, COSV58078018; called by muse, mutect2
- ALDH18A1 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64662723; called by muse, varscan2
- ATG9B | c.2204T>C p.V735A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.082); catalogued as COSV52490673; called by muse, varscan2
- F8 | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV64274323; called by muse, mutect2
- MAGEC3 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.807); catalogued as COSV53581315; called by muse, varscan2
- PLK2 | c.1858A>G p.T620A | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57107757; called by muse, mutect2, varscan2
- RTL9 | c.2535G>C p.M845I | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV71825684; called by muse, mutect2, varscan2
- SPON1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.186); catalogued as rs1554917278, COSV59962042; called by muse, varscan2
- TRIM10 | c.1180C>T p.L394F | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.172); called by muse, mutect2
- EDDM3B | c.399T>G p.V133= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV58747108; called by muse, mutect2, varscan2
- IFNA16 | c.312C>A p.L104= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV66510155; called by muse, mutect2, varscan2
- MACF1 | c.16227C>T p.G5409= (on ENST00000372915; = p.G3342= on NM_012090.5) | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV57124776; called by muse, mutect2, varscan2
- NDST4 | c.2088C>T p.P696= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV52122140; called by muse, mutect2, varscan2
- PLCB1 | c.3561C>T p.S1187= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV62054388; called by muse, mutect2, varscan2
- PPIP5K1 | c.4140C>T p.I1380= (on ENST00000396923; = p.I1355= on NM_014659.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs772329647, COSV55809480; called by muse, mutect2, varscan2
- PTCH2 | c.1494G>A p.T498= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs752335873, COSV64711420; called by muse, mutect2, varscan2
- TBXT | c.387G>A p.S129= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV51617342, COSV99752323; called by muse, mutect2, varscan2
- ZNF280C | c.1110C>T p.C370= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV63969040; called by muse, mutect2, varscan2
